Somatic mutation profile of tumor specimen C3N-03001-01 (aliquot CPT0248230006) from CPTAC case C3N-03001, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.0 years (29,230 days).
Specimen C3N-03001-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0bdbe69-0c74-4e4c-b79d-cc0dcd8ea149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03001-31 (Blood Derived Normal), aliquot CPT0248310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87accc81-3a0e-495d-a694-dca0d18ca8fc

The open-access MAF lists 87 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Intron 5, Frame Shift Del 3, RNA 2, 5'UTR 2, 3'UTR 2, Splice Site 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP5 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 157/606 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs771458690; called by muse, mutect2, varscan2
- ANKRD17 | c.6176G>A p.S2059N | Missense Mutation (SNP) | VAF 167/424 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as COSV58229966; called by muse, mutect2, varscan2
- ATP12A | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376103487; called by muse, mutect2, varscan2
- C3orf14 | c.163del p.S56Vfs*3 | Frame Shift Del (DEL) | VAF 65/185 reads (35%) | catalogued as COSV51706772; called by mutect2, pindel, varscan2
- CLCNKB | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1445924613, COSV100990521, COSV65160572; called by muse, mutect2, varscan2
- FOLH1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs116795343, COSV57047102; called by muse, mutect2, varscan2
- GAA | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as rs1464282302; called by muse, mutect2
- GABRA5 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 96/254 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59482675; called by muse, mutect2, varscan2
- GDF10 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 85/130 reads (65%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as rs782795294; called by muse, mutect2, varscan2
- HDC | c.1823del p.G608Afs*15 | Frame Shift Del (DEL) | VAF 191/639 reads (30%) | catalogued as COSV99983905; called by mutect2, pindel, varscan2
- HSPG2 | c.3149G>A p.G1050D | Missense Mutation (SNP) | VAF 134/368 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.809); catalogued as rs141501390; called by muse, mutect2, varscan2
- KIR2DL4 | c.134C>T p.T45M (on ENST00000396284; = p.T6M on NM_001080770.2) | Missense Mutation (SNP) | VAF 99/355 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs779579931; called by muse, mutect2, varscan2
- MAPK15 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 108/237 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs61736746; called by muse, mutect2, varscan2
- MNS1 | c.1331T>C p.I444T | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1567146067; called by muse, mutect2, varscan2
- NFKBIL1 | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.624); catalogued as rs1381538577; called by muse, varscan2
- PAGE5 | c.258T>A p.D86E | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV99215754; called by muse, mutect2, varscan2
- PLEKHA6 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs201387028; called by muse, mutect2, varscan2
- RFX6 | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60589085; called by muse, mutect2, varscan2
- RPS6KA2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs757805752, COSV55821063; called by muse, mutect2, varscan2
- RPUSD2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770620053; called by muse, mutect2, varscan2
- SETBP1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 121/289 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs773971820, COSV56322398, COSV56323609; called by muse, mutect2, varscan2
- SHROOM4 | c.1915C>T p.L639F | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV99172945; called by muse, mutect2, varscan2
- SLC14A2 | c.1350C>T p.S450= | Splice Region (SNP) | VAF 28/78 reads (36%) | catalogued as rs140835811; called by muse, mutect2
- SLC35A5 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs992603288; called by muse, mutect2, varscan2
- SLC38A5 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); catalogued as rs781879933; called by muse, mutect2, varscan2
- SULT1E1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV56946315; called by muse, mutect2, varscan2
- UNC13A | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 110/395 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53192297; called by muse, mutect2, varscan2
- ZNF224 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.887); catalogued as rs979267842; called by muse, mutect2, varscan2
- ZNF844 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.177); catalogued as COSV71518147; called by muse, mutect2, varscan2
- ZP3 | c.488C>T p.T163M (on ENST00000394857 / NM_001110354.2; = p.T112M on NM_007155.6) | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761504196; called by muse, mutect2, varscan2
- ASCL3 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C3orf52 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C4orf17 | c.337+1G>C p.X113_splice | Splice Site (SNP) | VAF 56/116 reads (48%) | called by muse, mutect2, varscan2
- CHAF1A | c.2450G>C p.C817S | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBG1 | c.4700T>C p.M1567T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DSG3 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- FAM90A10P | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 132/159 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by mutect2, varscan2
- GPRC6A | c.557T>C p.L186S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- HEATR3 | c.1259C>A p.T420K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ILK | c.1333A>G p.I445V | Missense Mutation (SNP) | VAF 133/342 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- IQSEC2 | c.2397C>A p.S799R (on ENST00000642864 / NM_001111125.3; = p.S594R on NM_015075.2) | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- JAG1 | c.1245_1248del p.C416Rfs*6 | Frame Shift Del (DEL) | VAF 102/531 reads (19%) | called by mutect2, pindel, varscan2
- KDM5A | c.2645C>G p.S882C | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- KMT2E | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LTK | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC12 | c.9782C>T p.T3261I (on ENST00000379442; = p.T3118I on NM_001164462.1) | Missense Mutation (SNP) | VAF 97/2006 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- NAV1 | c.1699C>A p.L567I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.083); called by muse, mutect2
- NBPF26 | c.3373C>G p.L1125V (on ENST00000620612; = p.L863V on NM_001351372.1) | Missense Mutation (SNP) | VAF 22/652 reads (3%) | SIFT tolerated (0.08); called by muse, mutect2
- PGK1 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLCB4 | c.2200A>G p.I734V | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PLSCR4 | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- SIGLEC16 | c.13T>C p.C5R | Missense Mutation (SNP) | VAF 40/174 reads (23%) | called by muse, mutect2, varscan2
- SLC5A3 | c.868A>G p.K290E | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX2 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 212/529 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPATA31D1 | c.1911G>A p.W637* | Nonsense Mutation (SNP) | VAF 163/437 reads (37%) | called by muse, mutect2, varscan2
- TCF25 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TEPP | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF222 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRF3 | c.2824C>T p.L942= (on ENST00000311519 / NM_001145168.1; = p.L743= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.2895C>T p.G965= | Silent (SNP) | VAF 120/312 reads (38%) | catalogued as rs761551059; called by muse, mutect2, varscan2
- COL15A1 | c.3558C>T p.A1186= | Silent (SNP) | VAF 82/206 reads (40%) | catalogued as rs753293203, COSV66642769; called by muse, mutect2, varscan2
- DHX35 | c.1572C>T p.P524= | Silent (SNP) | VAF 44/183 reads (24%) | called by muse, mutect2, varscan2
- GNA13 | c.930A>G p.L310= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs941409424; called by muse, mutect2, varscan2
- IKZF3 | c.1449C>T p.N483= | Silent (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- KIF4A | c.162A>G p.V54= | Silent (SNP) | VAF 61/137 reads (45%) | called by muse, mutect2, varscan2
- KMT2D | c.1491G>A p.P497= | Silent (SNP) | VAF 64/163 reads (39%) | catalogued as rs1438902528; called by muse, mutect2, varscan2
- KRT12 | c.1185G>A p.E395= | Silent (SNP) | VAF 85/192 reads (44%) | called by muse, mutect2, varscan2
- KRTAP21-2 | c.81T>C p.C27= | Silent (SNP) | VAF 93/211 reads (44%) | called by muse, mutect2, varscan2
- MKNK1 | c.1122G>A p.P374= | Silent (SNP) | VAF 66/185 reads (36%) | catalogued as rs550845828; called by muse, mutect2, varscan2
- OR1A2 | c.36T>C p.F12= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs766222296; called by muse, varscan2
- OR5M11 | c.63G>A p.P21= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs749588829, COSV73141962; called by muse, mutect2, varscan2
- PHF20 | c.114C>T p.Y38= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as rs779477634, COSV59188437; called by muse, mutect2, varscan2
- ROR2 | c.54C>A p.V18= | Silent (SNP) | VAF 115/288 reads (40%) | called by muse, mutect2, varscan2
- SHCBP1L | c.142C>A p.R48= | Silent (SNP) | VAF 122/304 reads (40%) | catalogued as rs775516849, COSV62356207; called by muse, mutect2, varscan2
- SLC35F3 | c.1155G>C p.L385= (on ENST00000366617 / NM_001300845.1; = p.L454= on NM_173508.4) | Silent (SNP) | VAF 179/478 reads (37%) | called by muse, mutect2, varscan2
- SRPK3 | c.1584C>T p.Y528= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as rs373971097, COSV54206986; called by muse, mutect2, varscan2
- ASPG | c.-18C>T | 5'UTR (SNP) | VAF 80/192 reads (42%) | called by muse, mutect2, varscan2
- EDAR | c.655+17G>A | Intron (SNP) | VAF 32/108 reads (30%) | catalogued as rs373163180; called by muse, mutect2, varscan2
- KIF1B | c.1181-15C>T | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- KIF23 | c.564-18del | Intron (DEL) | VAF 54/148 reads (36%) | called by mutect2, pindel, varscan2
- MYADML | n.685C>T | RNA (SNP) | VAF 97/227 reads (43%) | called by muse, mutect2, varscan2
- NPIPB10P | n.1344C>T | RNA (SNP) | VAF 42/221 reads (19%) | catalogued as rs1286732174; called by muse, mutect2, varscan2
- SEPTIN6 | c.1280+3925T>C | Intron (SNP) | VAF 68/159 reads (43%) | called by muse, mutect2, varscan2
- SPHK1 | c.-30C>T | 5'UTR (SNP) | VAF 129/271 reads (48%) | catalogued as rs1429507247; called by muse, mutect2, varscan2
- SSX3 | c.466+422G>T | Intron (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- TRPM4 | c.*1G>A | 3'UTR (SNP) | VAF 119/462 reads (26%) | called by muse, mutect2, varscan2
- ZNF99 | c.*245T>C | 3'UTR (SNP) | VAF 44/196 reads (22%) | catalogued as COSV101233700; called by muse, mutect2, varscan2
